Gene-level copy-number profile of tumor specimen TCGA-R6-A6DQ-01B from TCGA case TCGA-R6-A6DQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 74.2 years (27,098 days).
Specimen TCGA-R6-A6DQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.280fcc1c-e46a-4e2b-91a8-d335bc3b3f08.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6DQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/1519c0a0-cbf3-4f32-aaee-50a2bccfca13

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 911; copy number 2: 6,785; copy number 3: 23,278; copy number 4: 22,125; copy number 5: 4,765; copy number 6: 791; copy number 7: 1,034; copy number 8: 84; copy number 9: 44.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:6,057,807–6,207,269, 3 genes: WSCD1, AC104770.1, RNU6-1264P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 44 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:120,759,898–123,058,290, 44 genes, copy number 9 (within-gene range 4–9): WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB.

Autosomal genes at a single copy (total copy number 1): 911. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
